Somatic mutation profile of tumor specimen ALCH-B27A-TTP1-A (aliquot ALCH-B27A-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B27A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.2 years (21,971 days).
Specimen ALCH-B27A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80cecb2-b98b-4ff5-8236-69298075e2f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27A-NB1-A (Blood Derived Normal), aliquot ALCH-B27A-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec7fe22b-4865-415b-af87-e8621761ebb3

The open-access MAF lists 252 somatic variants for this specimen: 162 protein-altering or splice-affecting, 51 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 51, Intron 14, Nonsense Mutation 12, RNA 11, 5'UTR 6, 3'UTR 5, Splice Site 3, Frame Shift Del 2, 3'Flank 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 34/614 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- PAH | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 63/836 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs76542238, CM961086, COSV100188048; ClinVar: pathogenic; called by muse, mutect2
- STK11 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 22/319 reads (7%) | catalogued as rs121913324, CD132642, CM044071, COSV58819862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADCY2 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.658); catalogued as rs1296273812, COSV57885632; called by muse, mutect2
- ADCY8 | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs771922353; called by muse, mutect2, varscan2
- ADGRG4 | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs779183300; called by muse, mutect2
- ASXL3 | c.3296T>A p.L1099Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs187632583; called by muse, mutect2
- BNC2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs376354558; called by muse, mutect2
- CAND1 | c.2423G>T p.R808L | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs757657235, COSV73389531; called by muse, mutect2
- CATSPER4 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1249733084, COSV100128182; called by muse, mutect2
- CCDC142 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs1185463616; called by muse, varscan2
- CDH12 | c.1675C>A p.R559S | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs372690961, COSV66392476; called by muse, mutect2
- CPB1 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142894336; called by muse, mutect2
- CTNNA3 | c.2603G>T p.C868F | Missense Mutation (SNP) | VAF 43/681 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs768330893; called by muse, mutect2
- CYFIP2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs777932320; called by muse, mutect2
- CYSLTR1 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV64820551; called by muse, mutect2
- FAM122C | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV66195923; called by muse, mutect2
- FRMD7 | c.234G>C p.M78I | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV53744511; called by muse, mutect2
- GRK6 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100587108; called by muse, mutect2
- GYS1 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV54404842; called by muse, mutect2, varscan2
- HOXA10 | c.507C>A p.Y169* | Nonsense Mutation (SNP) | VAF 37/498 reads (7%) | catalogued as COSV99385667; called by muse, mutect2
- HYDIN | c.5620-1G>A p.X1874_splice | Splice Site (SNP) | VAF 42/520 reads (8%) | catalogued as COSV59260549, COSV99993581; called by muse, mutect2
- IFT80 | c.1142A>C p.Q381P | Missense Mutation (SNP) | VAF 30/627 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV58445532; called by muse, mutect2
- IGSF1 | c.2950G>T p.G984W | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100811761; called by muse, mutect2
- IRF8 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs370022572, COSV51896544; called by muse, mutect2
- KEAP1 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397945617, COSV50271135, COSV50276002; called by muse, mutect2
- LDB3 | c.1804T>A p.Y602N | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53945740; called by muse, mutect2
- LGSN | c.1071C>G p.C357W | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65727402; called by muse, mutect2
- METTL4 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 43/754 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV60603431; called by muse, mutect2
- MROH2B | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.998); catalogued as rs746569588, COSV68187342; called by muse, mutect2
- MRPS30 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1318005387; called by muse, mutect2
- MUC19 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 20/294 reads (7%) | catalogued as rs978176099, COSV101373726; called by muse, mutect2
- NAA35 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100863467; called by muse, mutect2
- NBEA | c.3968G>T p.G1323V | Missense Mutation (SNP) | VAF 82/940 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs761097921, COSV59764819; called by muse, mutect2
- NOS3 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224918607, COSV52488969; called by muse, mutect2
- OR2G2 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740804, COSV60740826; called by muse, mutect2, varscan2
- OR4N2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100269369; called by muse, mutect2
- PCDH1 | c.2665G>T p.G889C | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54614660; called by muse, mutect2
- PCDHA5 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV65354075; called by muse, mutect2
- PCDHB8 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 54/1385 reads (4%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.011); catalogued as rs781820369, COSV99175180; called by muse, mutect2
- PDCD10 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as CM108378, COSV67102899, COSV67103186; called by muse, mutect2
- PDE8A | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as rs775184576; called by muse, mutect2, varscan2
- PGM1 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 72/906 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as rs576570314; called by muse, mutect2
- PHKB | c.2861A>G p.N954S | Missense Mutation (SNP) | VAF 73/961 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs147624679; called by muse, mutect2
- PLXNA3 | c.3040G>T p.G1014W | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63755857; called by muse, mutect2
- POM121L2 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1411165893; called by muse, mutect2
- POM121L2 | c.2213G>T p.W738L | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV66276432; called by muse, mutect2
- PSAPL1 | c.381C>G p.D127E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1388777682; called by muse, mutect2, varscan2
- PSKH2 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs145737809; called by muse, mutect2, varscan2
- RELN | c.4647G>C p.L1549F | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs769890427; called by muse, mutect2
- RYR3 | c.10453G>T p.A3485S (on ENST00000389232; = p.A3486S on NM_001036.6) | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66777358; called by muse, mutect2
- SHROOM4 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV99174905; called by muse, mutect2
- SLC26A7 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52595859; called by muse, mutect2
- SLC6A15 | c.1276T>A p.C426S | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV57022487; called by muse, mutect2, varscan2
- TANC2 | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.899); catalogued as rs201847314; called by muse, mutect2
- TNNT2 | c.692T>A p.I231N (on ENST00000236918; = p.I228N on NM_000364.4) | Missense Mutation (SNP) | VAF 89/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM1310647; called by muse, mutect2, varscan2
- TRPM6 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62521761; called by muse, mutect2
- VAV3 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs748006794, COSV58388140; called by muse, mutect2
- ZFHX4 | c.2447C>A p.A816E | Missense Mutation (SNP) | VAF 30/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776758893, COSV50721475; called by muse, mutect2
- ZNF235 | c.1167T>A p.D389E | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs1177499803, COSV52156659; called by muse, mutect2, varscan2
- ABCA6 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 18/411 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.189); called by muse, mutect2
- ACCS | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACOT12 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/188 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- ADCYAP1R1 | c.879C>A p.D293E | Missense Mutation (SNP) | VAF 17/400 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ADGRF4 | c.1758G>T p.R586S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AOPEP | c.154A>T p.R52* | Nonsense Mutation (SNP) | VAF 26/500 reads (5%) | called by muse, mutect2
- ARHGEF33 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- ARMCX6 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATG9A | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.143); called by muse, mutect2
- ATP5F1B | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.36); called by muse, mutect2
- B4GALT3 | c.410A>T p.H137L | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BPIFB4 | c.189C>A p.Y63* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, varscan2
- CCDC142 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, varscan2
- CFAP99 | c.299C>A p.A100E (on ENST00000506607; = p.A585E on NM_001193282.3) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, varscan2
- CHD1 | c.5005A>T p.R1669* | Nonsense Mutation (SNP) | VAF 76/915 reads (8%) | called by muse, mutect2
- CHD4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CIAO1 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2
- CYSLTR1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.201); called by muse, mutect2
- DCC | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 49/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCC | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 55/776 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH5 | c.10022T>A p.L3341Q | Missense Mutation (SNP) | VAF 132/1238 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNASE2B | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, varscan2
- DSPP | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 46/1427 reads (3%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.065); called by muse, mutect2
- EXOC6B | c.1300A>T p.S434C | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- EXTL2 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM135A | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- FETUB | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 19/536 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGF4 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXO3 | c.1463A>T p.Q488L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GALNT17 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GLT1D1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.1); called by muse, mutect2
- GPHN | c.1314+1G>A p.X438_splice (on ENST00000315266 / NM_001377519.1; = p.X471_splice on NM_020806.5) | Splice Site (SNP) | VAF 58/906 reads (6%) | called by muse, mutect2
- HEMGN | c.173+2T>A p.X58_splice | Splice Site (SNP) | VAF 44/382 reads (12%) | called by muse, varscan2
- HTR5A | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- IGHM | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.398); called by muse, mutect2
- ILDR2 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IQCA1 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 39/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRAK1 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- IZUMO3 | c.421G>T p.G141C (on ENST00000543880 / NM_001365008.2; = p.G135C on NM_001271706.1) | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- KIAA1328 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2
- KIF7 | c.1964del p.P655Qfs*65 | Frame Shift Del (DEL) | VAF 29/320 reads (9%) | called by mutect2, pindel
- KLHDC4 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- KRBOX1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 34/637 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.678); called by muse, mutect2
- KRT82 | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2
- KRT82 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2
- LPA | c.4831C>A p.P1611T | Missense Mutation (SNP) | VAF 78/828 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.214); called by muse, mutect2
- LRRTM4 | c.768C>A p.H256Q | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- MAGEA12 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 29/480 reads (6%) | called by muse, mutect2
- MYH4 | c.5338A>G p.S1780G | Missense Mutation (SNP) | VAF 60/710 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2
- MYO9B | c.1288G>T p.G430W | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- NECTIN3 | c.1388A>T p.D463V | Missense Mutation (SNP) | VAF 51/786 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- NFIA | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR14A16 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2
- OR2L13 | c.453del p.S152Pfs*49 | Frame Shift Del (DEL) | VAF 103/680 reads (15%) | called by mutect2, pindel, varscan2
- OR4C46 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- OR7E24 | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PATJ | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- PCDHB5 | c.1624A>T p.S542C | Missense Mutation (SNP) | VAF 27/534 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDIA6 | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- POLR2B | c.3030G>T p.K1010N | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.597); called by muse, mutect2
- PRAMEF18 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 22/606 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- PSKH2 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCH2 | c.2655G>A p.W885* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- PTCH2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2
- PTCH2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- QSOX1 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- RCHY1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2
- RELN | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RPH3A | c.1726C>A p.H576N (on ENST00000389385 / NM_001143854.2; = p.H572N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RPL5 | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 44/732 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- SAMD9 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 27/496 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- SART1 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- SCRT2 | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SI | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SNX7 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 86/1116 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); called by muse, mutect2
- SPATA31A6 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 29/578 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.076); called by muse, mutect2
- STK33 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SULF1 | c.1504A>T p.K502* | Nonsense Mutation (SNP) | VAF 31/304 reads (10%) | called by muse, mutect2, varscan2
- TAAR9 | c.785T>A p.I262N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TBC1D9 | c.477A>C p.K159N | Missense Mutation (SNP) | VAF 63/662 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOP2A | c.1798A>C p.S600R | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- TPTE | c.979G>T p.A327S (on ENST00000618007 / NM_199261.4; = p.A309S on NM_199259.4) | Missense Mutation (SNP) | VAF 46/1130 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2
- TRBV23-1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- TRIM49B | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRMT13 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); called by muse, mutect2
- UBA6 | c.1808T>C p.I603T | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- UBR2 | c.4867G>T p.G1623C | Missense Mutation (SNP) | VAF 50/574 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- UNC5C | c.1954C>A p.L652M | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- URB1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- USH2A | c.9208G>T p.G3070W | Missense Mutation (SNP) | VAF 57/928 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP24 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP26 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.01); called by muse, mutect2
- WDR72 | c.3260C>A p.P1087Q | Missense Mutation (SNP) | VAF 93/1170 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2
- ZDHHC15 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZDHHC19 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ZFHX4 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.036); called by muse, mutect2
- ZGRF1 | c.5854G>T p.G1952* | Nonsense Mutation (SNP) | VAF 16/606 reads (3%) | called by muse, mutect2
- ZNF311 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2
- ZNF479 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF676 | c.149C>A p.P50Q (on ENST00000650058; = p.P18Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF746 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 33/583 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2
- ADCY10 | c.4635G>C p.G1545= | Silent (SNP) | VAF 34/1072 reads (3%) | catalogued as COSV63238767; called by muse, mutect2
- ADGRA1 | c.109C>A p.R37= | Silent (SNP) | VAF 12/104 reads (12%) | called by mutect2, varscan2
- AKAP1 | c.1290A>T p.P430= | Silent (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- ALS2CL | c.1695G>T p.L565= | Silent (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- ANKRD33B | c.1368C>A p.P456= | Silent (SNP) | VAF 21/301 reads (7%) | called by muse, mutect2
- AP3B2 | c.6G>T p.S2= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- CABIN1 | c.2058G>T p.S686= | Silent (SNP) | VAF 34/404 reads (8%) | called by muse, mutect2
- CACNA1S | c.4701C>A p.A1567= | Silent (SNP) | VAF 46/280 reads (16%) | catalogued as COSV62936798; called by muse, mutect2, varscan2
- CCZ1 | c.1269G>C p.V423= | Silent (SNP) | VAF 24/766 reads (3%) | called by muse, mutect2
- CDH20 | c.1083G>A p.E361= | Silent (SNP) | VAF 44/613 reads (7%) | catalogued as rs866313451, COSV53016351; called by muse, mutect2
- CENPE | c.5541T>G p.S1847= | Silent (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- CGNL1 | c.1278G>C p.P426= | Silent (SNP) | VAF 30/460 reads (7%) | called by muse, mutect2
- EGFL6 | c.1311G>T p.P437= | Silent (SNP) | VAF 19/239 reads (8%) | called by muse, mutect2
- FAM135B | c.2184A>G p.L728= | Silent (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- FLRT1 | c.876G>A p.K292= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- FLRT1 | c.1179G>A p.K393= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs747777424; called by muse, mutect2
- GALNT14 | c.267C>T p.S89= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV100204146; called by muse, mutect2
- GRK6 | c.135G>T p.L45= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- H2BW1 | c.381C>A p.S127= | Silent (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- ITIH6 | c.174C>A p.V58= | Silent (SNP) | VAF 34/406 reads (8%) | called by muse, mutect2
- LCNL1 | c.327G>A p.R109= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- LRPPRC | c.870G>T p.L290= | Silent (SNP) | VAF 74/942 reads (8%) | called by muse, mutect2
- LVRN | c.150A>T p.G50= | Silent (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- MAST2 | c.1257C>T p.I419= | Silent (SNP) | VAF 20/323 reads (6%) | catalogued as COSV100788758; called by muse, mutect2
- MROH2A | c.1830C>A p.I610= | Silent (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- MVB12B | c.798T>G p.S266= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- NDUFA1 | c.72G>A p.A24= | Silent (SNP) | VAF 34/414 reads (8%) | catalogued as COSV65097402; called by muse, mutect2
- NEB | c.4131C>A p.T1377= | Silent (SNP) | VAF 74/982 reads (8%) | called by muse, mutect2
- OBSCN | c.15621C>T p.V5207= | Silent (SNP) | VAF 6/151 reads (4%) | called by muse, mutect2
- OR10A7 | c.297C>A p.T99= | Silent (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- OR14A16 | c.834G>T p.L278= | Silent (SNP) | VAF 30/357 reads (8%) | called by muse, mutect2
- OR1M1 | c.273C>G p.A91= | Silent (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- OR2AK2 | c.891G>T p.V297= | Silent (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- OR4C46 | c.381C>A p.P127= | Silent (SNP) | VAF 38/416 reads (9%) | catalogued as COSV60218537; called by muse, mutect2
- OR4K5 | c.717G>C p.T239= | Silent (SNP) | VAF 54/648 reads (8%) | catalogued as COSV100262301; called by muse, mutect2
- OR51V1 | c.825C>A p.A275= | Silent (SNP) | VAF 36/390 reads (9%) | called by muse, mutect2
- PARD3B | c.255C>T p.L85= | Silent (SNP) | VAF 38/372 reads (10%) | catalogued as rs1049807329; called by muse, mutect2
- PCID2 | c.447C>T p.F149= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs753303087; called by muse, mutect2, varscan2
- PCSK5 | c.4932C>T p.L1644= | Silent (SNP) | VAF 22/327 reads (7%) | called by muse, mutect2
- PEX5L | c.804G>A p.R268= | Silent (SNP) | VAF 22/466 reads (5%) | catalogued as COSV55846578; called by muse, mutect2
- PIK3R5 | c.1341G>C p.S447= | Silent (SNP) | VAF 15/221 reads (7%) | catalogued as COSV99353199; called by muse, mutect2
- PRMT7 | c.603G>T p.V201= | Silent (SNP) | VAF 26/506 reads (5%) | called by muse, mutect2
- PTPRN | c.1812G>A p.A604= | Silent (SNP) | VAF 30/398 reads (8%) | catalogued as rs372877795; called by muse, mutect2
- SDS | c.75C>T p.T25= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- SHROOM4 | c.312C>A p.A104= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- SLC15A1 | c.720C>T p.I240= | Silent (SNP) | VAF 43/399 reads (11%) | catalogued as rs770731724; called by muse, mutect2, varscan2
- STX8 | c.147G>A p.Q49= | Silent (SNP) | VAF 20/408 reads (5%) | catalogued as rs911010488; called by muse, mutect2
- TECPR2 | c.45G>A p.P15= | Silent (SNP) | VAF 35/579 reads (6%) | catalogued as rs371781829; called by muse, mutect2
- TRPM1 | c.2097G>T p.L699= | Silent (SNP) | VAF 54/868 reads (6%) | called by muse, mutect2
- TUBGCP6 | c.4509T>C p.A1503= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs902019556; called by muse, mutect2
- ZNF669 | c.648A>G p.P216= | Silent (SNP) | VAF 56/306 reads (18%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3905G>T | Intron (SNP) | VAF 68/681 reads (10%) | called by muse, mutect2, varscan2
- ADARB2 | c.-1C>A | 5'UTR (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- AL162726.3 | n.255+83286G>T | Intron (SNP) | VAF 36/822 reads (4%) | called by muse, mutect2
- AP000851.2 | n.333C>A | RNA (SNP) | VAF 39/340 reads (11%) | catalogued as rs1469143138; called by muse, mutect2, varscan2
- AP001830.2 | n.263T>C | RNA (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ARHGEF4 | c.-221C>A | 5'UTR (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- ASF1B | c.*14G>A | 3'UTR (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- ATP2A1 | c.119-53dup | Intron (INS) | VAF 14/130 reads (11%) | called by mutect2, pindel, varscan2
- BMS1P15 | n.445G>T | RNA (SNP) | VAF 26/434 reads (6%) | called by muse, mutect2
- CPLX2 | c.208-88A>T | Intron (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- DCXR | c.349-12C>T | Intron (SNP) | VAF 42/510 reads (8%) | called by muse, mutect2
- DIO2 | c.223-2343G>T | Intron (SNP) | VAF 19/406 reads (5%) | called by muse, mutect2
- FAM205BP | n.1902C>T | RNA (SNP) | VAF 50/1162 reads (4%) | catalogued as rs1400981277; called by muse, mutect2
- GTF2IRD2P1 | n.1808A>T | RNA (SNP) | VAF 18/413 reads (4%) | called by muse, mutect2
- GVINP1 | n.4688G>T | RNA (SNP) | VAF 25/265 reads (9%) | called by muse, mutect2
- IFT122 | c.349+48G>T | Intron (SNP) | VAF 27/355 reads (8%) | called by muse, mutect2
- IGHV7-81 | c.-21C>T | 5'UTR (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- IGKV1-13 | n.320A>T | RNA (SNP) | VAF 70/1912 reads (4%) | called by muse, mutect2
- JPT2 | c.*128G>T | 3'UTR (SNP) | VAF 46/506 reads (9%) | called by muse, mutect2
- KCNC1 | chr11:17779564 G>C | 3'Flank (SNP) | VAF 10/196 reads (5%) | catalogued as COSV56396056; called by muse, mutect2
- LMO2 | c.-272+612G>T | Intron (SNP) | VAF 34/578 reads (6%) | called by muse, mutect2
- MCFD2 | c.309+10G>T | Intron (SNP) | VAF 28/441 reads (6%) | called by muse, mutect2
- MIR545 | n.19T>A | RNA (SNP) | VAF 37/580 reads (6%) | called by muse, mutect2
- MKRN9P | n.258T>C | RNA (SNP) | VAF 29/363 reads (8%) | called by muse, mutect2
- NPC1 | c.-50G>T | 5'UTR (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- NUP160 | c.1102-4969C>T | Intron (SNP) | VAF 38/501 reads (8%) | catalogued as rs559231818; called by muse, mutect2
- RNA5-8SP2 | chr16:34159871 del G | 5'Flank (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- SERPINA13P | n.1149C>T | RNA (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- SPEF2 | c.4448-2418C>A | Intron (SNP) | VAF 36/376 reads (10%) | called by muse, mutect2
- SSPOP | n.14030C>A | RNA (SNP) | VAF 27/302 reads (9%) | called by muse, mutect2
- TGFB2 | c.346+16307A>G | Intron (SNP) | VAF 40/454 reads (9%) | called by muse, mutect2
- TGFBR3 | c.*739G>T | 3'UTR (SNP) | VAF 20/369 reads (5%) | called by muse, mutect2
- TMEM167A | c.-24G>T | 5'UTR (SNP) | VAF 19/347 reads (5%) | called by muse, mutect2
- TPR | c.-15C>T | 5'UTR (SNP) | VAF 83/530 reads (16%) | catalogued as rs775868638; called by muse, mutect2, varscan2
- U8 | chr15:32424704 A>C | 3'Flank (SNP) | VAF 22/657 reads (3%) | catalogued as rs754949201; called by muse, mutect2
- UBE2Q2 | c.180+582G>T | Intron (SNP) | VAF 22/396 reads (6%) | called by muse, mutect2
- VAPB | c.*2042G>A | 3'UTR (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1319C>A | 3'UTR (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ZNF497 | c.-111-290G>A | Intron (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
